Gene-level copy-number profile of tumor specimen ALCH-B78N-TTP1-A from ALCHEMIST case ALCH-B78N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.9 years (26,258 days).
Specimen ALCH-B78N-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8eb3ca5b-eae0-4858-a3fc-ee50ae02db33.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B78N-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/3c985414-805d-4cb9-82e2-89245f2932e7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 3,838; copy number 2: 54,195; copy number 3: 301; copy number 4: 5; copy number 5: 1; copy number 6: 1; copy number 8: 5; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,412,418–6,424,670, 1 gene: HES2.
- chr1:6,429,834–6,429,896, 1 gene (within-gene range 0–2): MIR4252.
- chr1:54,779,712–54,801,323, 2 genes: TTC22, AC096536.1.
- chr2:91,686,102–91,714,745, 1 gene: AC027612.2.
- chr2:120,319,007–120,326,298, 1 gene: AC012363.2.
- chr11:128,934,731–128,943,399, 1 gene: TP53AIP1.
- chr14:34,568,689–34,569,129, 1 gene (within-gene range 0–2): RPS19P3.
- chr15:25,187,536–25,225,284, 21 genes (within-gene range 0–2): SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:67,019,934–67,033,290, 2 genes (within-gene range 0–2): AC005544.1, AC005544.2.
- chr18:14,143,596–14,157,342, 2 genes: AC006557.2, NF1P5.
- chr18:63,476,958–63,505,085, 3 genes: SERPINB5, AC036176.3, ATP5MC1P6.
- chr20:32,561,093–32,608,893, 3 genes (within-gene range 0–2): AL133343.2, NOL4L-DT, AL133343.1.
- chr20:62,410,237–62,475,995, 3 genes: RBBP8NL, AL121832.1, GATA5.
- chr22:22,547,701–22,559,361, 1 gene (within-gene range 0–2): PRAME.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:109,792,758–109,985,124, 5 genes, copy number 8 (within-gene range 2–8): RGPD5, LIMS3, AC013271.1, AC013268.1, AC013268.5.
- chr2:110,007,675–110,010,783, 1 gene, copy number 16: AC013268.3.
- chr8:12,412,827–12,414,373, 1 gene, copy number 6: AC087203.3.
- chr20:62,386,303–62,386,970, 1 gene, copy number 5: AL121832.2.

Autosomal genes at a single copy (total copy number 1): 3,836. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
